Somatic mutation profile of tumor specimen 0DWGJF from CCDI case PBCJVI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.7 years (2,440 days).
Specimen 0DWGJF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8bc829e-bb0d-4403-8097-3c0f5e5d896b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWGIY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0590bdb3-a7ae-4a9b-bd41-947b45bb6923

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRYBG2 | c.4737+1G>A p.X1579_splice | Splice Site (SNP) | VAF 37/223 reads (17%) | catalogued as rs751420327; called by muse, mutect2, varscan2
- BRPF3 | c.2238G>A p.K746= | Silent (SNP) | VAF 66/390 reads (17%) | catalogued as rs1244564376; called by muse, mutect2, varscan2
- IQCH | c.912C>T p.H304= | Silent (SNP) | VAF 47/327 reads (14%) | catalogued as rs764780502, COSV60055919; called by muse, mutect2, varscan2
- SPIRE2 | c.1140C>A p.S380= | Silent (SNP) | VAF 126/367 reads (34%) | called by muse, mutect2, varscan2
- COL3A1 | c.283-39T>C | Intron (SNP) | VAF 12/258 reads (5%) | called by muse, mutect2
